Gene-level copy-number profile of tumor specimen HCM-SANG-0314-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0314-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0314-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4425d425-22a9-4ede-98dd-c81901bd52e2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0314-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/f7484f00-9432-43d1-967e-c296305edaef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 7,129; copy number 2: 42,645; copy number 3: 6,052; copy number 4: 1,753; copy number 5: 1,330.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:112,452,703–112,642,483, 3 genes: HMGB3P16, AC137549.1, LINC02200.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–4): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,330 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
